Somatic mutation profile of tumor specimen 0DGFVT from CCDI case PBBTKI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.0 years (1,080 days).
Specimen 0DGFVT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a94c1df0-8cf9-4f0a-b1ef-28e6e080eaa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGFTM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbedab2b-d065-425f-89a9-b9d6e12c6ae9

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 392/411 reads (95%) | catalogued as rs1060503015, CM110286, COSV54092906, COSV54099377; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXF1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 228/500 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52285946; called by muse, mutect2, varscan2
- TCHH | c.2967dup p.Y990Ifs*228 | Frame Shift Ins (INS) | VAF 120/1042 reads (12%) | catalogued as rs762531745; called by mutect2, varscan2
- XRN1 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 66/762 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.339); catalogued as rs141258147; called by muse, mutect2
- BORA | c.637C>T p.P213S (on ENST00000613797; = p.P138S on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2
- SCMH1 | c.1294C>G p.Q432E (on ENST00000326197 / NM_001031694.2; = p.Q385E on NM_012236.4) | Missense Mutation (SNP) | VAF 255/566 reads (45%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- SYTL5 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBCK | c.593G>A p.C198Y (on ENST00000273980 / NM_001163436.4; = p.C135Y on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/480 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADAMTS16 | c.402G>A p.K134= | Silent (SNP) | VAF 199/460 reads (43%) | catalogued as COSV56982827, COSV56985252; called by muse, mutect2, varscan2
- DNMT3B | c.477G>A p.P159= | Silent (SNP) | VAF 253/615 reads (41%) | catalogued as rs375939126; called by muse, mutect2, varscan2
- ZNF449 | c.1368G>A p.T456= | Silent (SNP) | VAF 319/687 reads (46%) | catalogued as rs138335708, COSV59347442; called by muse, mutect2, varscan2
- ZNF71 | c.564C>T p.C188= | Silent (SNP) | VAF 145/374 reads (39%) | called by muse, mutect2, varscan2
- ACTRT1 | c.*2G>T | 3'UTR (SNP) | VAF 334/761 reads (44%) | catalogued as COSV100947512; called by mutect2, varscan2
- NRXN1 | c.820+44T>C | Intron (SNP) | VAF 247/543 reads (45%) | called by muse, mutect2, varscan2
